Gene-level copy-number profile of tumor specimen ALCH-ACGZ-TTP1-A from ALCHEMIST case ALCH-ACGZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 38.5 years (14,067 days).
Specimen ALCH-ACGZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 602b6c0c-422f-4c1b-b54e-716c19735005.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ACGZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/b61c530a-ca98-42fc-abcd-6985e0a0559f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 7,339; copy number 2: 48,959; copy number 3: 2,044; copy number 4: 29; copy number 5: 8.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:131,461,821–131,463,615, 1 gene: AC073869.1.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr6:40,271,566–40,276,237, 1 gene: AL139275.2.
- chr18:45,034–46,047, 1 gene: AP001005.1.
- chr19:41,449,520–41,532,174, 4 genes: PCAT19, AC243960.2, PLEKHA3P1, AC243960.3.
- chr19:43,035,869–43,041,248, 1 gene (within-gene range 0–1): CEACAMP8.
- chr20:32,983,773–33,004,433, 1 gene: SUN5.
- chr22:41,952,174–41,998,221, 3 genes: LINC00634, SEPTIN3, Z99716.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:42,849,637–42,897,290, 3 genes, copy number 5 (within-gene range 3–5): RNF170, RN7SL806P, MIR4469.
- chr11:62,602,218–62,612,775, 2 genes, copy number 5 (within-gene range 4–5): EML3, AP001458.1.
- chr21:10,649,400–13,016,692, 2 genes, copy number 5: IGHV1OR21-1, AP001464.1.
- chr21:13,095,305–13,113,790, 1 gene, copy number 5: ZNF355P.

Autosomal genes at a single copy (total copy number 1): 7,339. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
